CMI case ASCProject_0026 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/6c8b33a7-3629-477c-9dc3-930eb34f1bd2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 56.5 years (20,651 days).

Biospecimens (3 samples)
- Sample ASCProject_0026_BLOOD_Normal: Sample type: DNA; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood.
- Samples ASCProject_0026_T1_RNA, ASCProject_0026_T1_WES (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
